CGCI case BLGSP-71-06-00146 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d691aab7-cdcd-4c0a-8294-91e29f97c00f

Demographics
Sex at birth: female; Race: black or african american; Age at index: 10 years; Vital status: Dead; Days to death: 6 days.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: primary; Year of diagnosis: 2014; Method of diagnosis: Biopsy; Ann Arbor pathologic stage: Stage III; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 6 days; Ann Arbor extranodal involvement: Yes; Max tumor bulk site: Other; Sites of involvement: Eye / Mandible / Maxilla / Abdomen.
   Pathology details: Lymph node involved site: Occipital; Tumor largest dimension diameter: 15 cm.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 0 days; Disease response: With Tumor; Karnofsky performance status: 60; ECOG performance status: 3.
- Days to follow up: 6 days; Disease response: With Tumor.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Abnormal, NOS.
- MYC translocation (FISH): Positive.
- Lactate Dehydrogenase 871 [Blood test normal range upper: 298].

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-06-00146-01C: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Tissue collection type: Prospective.
  Slide BLGSP-71-06-00146-01-HE: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 0; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 30; Percent neutrophil infiltration: 10.
- Sample BLGSP-71-06-00146-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample BLGSP-71-06-00146-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Lymphocytes; Preservation method: Frozen; Tissue collection type: Prospective.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: With tumor; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Extranodal site involvement: 4; Extranodal involvment other: Intra-abdominal; Method initial path diagnosis: Other method, specify:; Method initial path diagnosis other: Tru cut; Lymph nodes examined: No.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- Tests performed: LDH level: 871; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunophenotypic analysis tested: CD3.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result: Genetic abnormality tested: C-myc.
- Treatments, Treatment: Therapy regimen: Initial; Treatment type: No Treatment.
